Gene-level copy-number profile of tumor specimen TCGA-C5-A1BJ-01A from TCGA case TCGA-C5-A1BJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 34.5 years (12,611 days).
Specimen TCGA-C5-A1BJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.83136251-d7be-4805-9eab-ef1c7ebfafaa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1BJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/622e627a-7675-41ad-a267-838590f2ea0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,384; copy number 2: 45,860; copy number 3: 4,009; copy number 4: 2,192; copy number 5: 173; copy number 6: 26; copy number 8: 1; copy number 9: 33; copy number 10: 10; copy number 11: 2; copy number 12: 12; copy number 17: 19; copy number 18: 1; copy number 20: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1BJ-01A-11D-A13V-01): tumor purity 0.4, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 368 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,258,745–169,396,540, 185 genes, copy number 5–11 (within-gene range 1–11) (broad region; genes not listed).
- chr11:101,451,564–104,252,651, 58 genes, copy number 6–18: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1.
- chr17:20,814,620–21,594,180, 34 genes, copy number 6–12: ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2.
- chr19:37,091,341–39,111,493, 91 genes, copy number 20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,384. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
